Somatic mutation profile of tumor specimen TCGA-SC-A6LQ-01A (aliquot TCGA-SC-A6LQ-01A-11D-A34C-32) from TCGA case TCGA-SC-A6LQ, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.3 years (22,014 days).
Specimen TCGA-SC-A6LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67b09e44-c479-4214-bf3f-0f9bb499b3f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-A6LQ-10A (Blood Derived Normal), aliquot TCGA-SC-A6LQ-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc071576-f7c9-4c79-ae9f-6c592bdf0f0d

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, In Frame Del 3, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as rs747332721, COSV101038587; called by muse, mutect2, varscan2
- AVPR2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs905300222, COSV61685804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBLL1 | c.2806G>A p.A936T (on ENST00000392717; = p.A898T on NM_014900.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52067261; called by muse, mutect2, varscan2
- GABRB1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99783848; called by muse, mutect2, varscan2
- PCDHA7 | c.1768G>C p.V590L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); catalogued as COSV65345641; called by muse, mutect2, varscan2
- SGO1 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV55422757; called by muse, mutect2, varscan2
- SLAIN2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755781451, COSV51908073; called by muse, mutect2, varscan2
- SLC39A11 | c.898G>A p.G300S (on ENST00000542342 / NM_001159770.2; = p.G293S on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776994238, COSV99723745; called by muse, mutect2, varscan2
- ACER3 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- APMAP | c.1189C>G p.H397D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARID1A | c.363_388del p.G122Wfs*269 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- CSF1R | c.1453T>C p.C485R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMC9 | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- MDC1 | c.4852G>T p.E1618* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- NF2 | c.248_286del p.D83_F96delinsV | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- NRAP | c.1907A>T p.N636I (on ENST00000359988 / NM_001322945.2; = p.N601I on NM_006175.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- PARM1 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBRM1 | c.2996_3013del p.Y999_T1004del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- RFX1 | c.1258A>G p.M420V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SPTA1 | c.4747G>C p.E1583Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STX1B | c.523_525del p.I175del | In Frame Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- TRIM72 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.053); called by mutect2, varscan2
- ZZZ3 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- AGAP2 | c.2919C>T p.H973= (on ENST00000547588 / NM_001122772.2; = p.H617= on NM_014770.4) | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs758179910, COSV57727319; called by muse, mutect2, varscan2
- ELMO3 | c.1545G>A p.E515= (on ENST00000652269; = p.E462= on NM_024712.5) | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- KLF11 | c.1059C>G p.P353= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs761363367; called by muse, mutect2, varscan2
- PGAP6 | c.1896G>A p.L632= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- SLC38A1 | c.1311T>G p.L437= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1208797116; called by muse, mutect2
- TSPAN18 | c.624C>T p.Y208= | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- ZNF433 | c.1446T>C p.G482= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs1232967062; called by muse, mutect2, varscan2
